Gene-level copy-number profile of tumor specimen ALCH-ADIP-TTP1-A from ALCHEMIST case ALCH-ADIP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.5 years (24,302 days).
Specimen ALCH-ADIP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 518d41b2-fe06-4882-931a-f301cdf9787c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADIP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,745 have no estimate.
https://portal.gdc.cancer.gov/files/cc6e1b81-7e7c-4c9d-8fe2-f4bcb7161a0a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 73; copy number 1: 5,486; copy number 2: 51,012; copy number 3: 2,176; copy number 4: 75; copy number 5: 19; copy number 6: 8; copy number 7: 4; copy number 8: 10; copy number 9: 8; copy number 12: 4; copy number 17: 1; copy number 25: 1; copy number 55: 1.

Homozygous deletions (total copy number 0; autosomes only): 73 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,651,731–9,729,114, 4 genes (within-gene range 0–2): PIK3CD, PIK3CD-AS1, AL691449.1, PIK3CD-AS2.
- chr1:241,957,767–241,959,062, 1 gene: BECN2.
- chr2:91,747,940–91,748,986, 1 gene (within-gene range 0–1): KMT5AP2.
- chr4:8,858,715–8,860,827, 1 gene (within-gene range 0–1): AC116612.1.
- chr5:176,542,511–176,595,974, 3 genes (within-gene range 0–1): CDHR2, RN7SL684P, Y_RNA.
- chr6:73,322,837–73,452,297, 10 genes: SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS.
- chr6:107,065,182–107,115,515, 1 gene: BEND3.
- chr6:168,194,358–168,204,501, 1 gene: AL611929.1.
- chr7:6,855,485–6,859,830, 1 gene: UNC93B2.
- chr7:56,875,385–56,882,146, 1 gene: AC118758.1.
- chr7:76,173,733–76,177,205, 1 gene: AC005077.3.
- chr7:140,404,058–140,435,787, 2 genes (within-gene range 0–2): RAB19, AC069335.1.
- chr7:152,590,641–152,609,434, 4 genes: AC104843.2, 5S_rRNA, AC104843.1, AC003109.1.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr9:61,190,003–61,582,675, 8 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr9:136,796,338–136,810,042, 2 genes (within-gene range 0–4): CCDC183, AL355987.4.
- chr9:136,803,927–136,808,848, 1 gene (within-gene range 0–4): CCDC183-AS1.
- chr9:137,188,660–137,190,370, 1 gene: SSNA1.
- chr9:137,204,082–137,205,648, 1 gene (within-gene range 0–1): TMEM203.
- chr11:70,705,167–70,706,068, 2 genes (within-gene range 0–1): Y_RNA, AP000590.1.
- chr11:71,428,193–71,524,107, 5 genes (within-gene range 0–2): DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2.
- chr12:122,167,738–122,203,471, 2 genes: LRRC43, IL31.
- chr14:93,138,066–93,138,465, 1 gene: CYB5AP3.
- chr14:94,726,288–94,770,113, 2 genes: RPSAP4, GSC.
- chr15:20,008,402–20,291,586, 11 genes: IGHD2OR15-2A, IGHD1OR15-1A, FAM30B, AC127381.1, BCAR1P1, RN7SL584P, AC087386.1, AC087386.2, BMS1P15, RHPN2P1, CHEK2P2.
- chr19:1,576,939–1,577,086, 1 gene (within-gene range 0–3): AC005943.2.
- chr20:56,629,306–56,667,531, 2 genes: TFAP2C, RNU6-1146P.
- chr22:16,521,059–16,527,237, 1 gene: AP000547.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 56 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:143,915,153–144,012,772, 4 genes, copy number 5 (within-gene range 4–6): PLEC, MIR661, PARP10, GRINA.
- chr8:144,049,079–144,051,522, 1 gene, copy number 5: SMPD5.
- chr9:136,754,386–136,780,218, 3 genes, copy number 5–7: LCN8, LCN15, ATP6V1G1P3.
- chr9:136,844,415–136,860,799, 3 genes, copy number 9 (within-gene range 3–9): AJM1, PHPT1, MAMDC4.
- chr9:136,969,243–136,971,990, 1 gene, copy number 6: LINC02692.
- chr9:136,981,904–136,993,984, 2 genes, copy number 6 (within-gene range 3–6): LCNL1, PAXX.
- chr9:137,031,241–137,046,179, 2 genes, copy number 5 (within-gene range 2–5): AL807752.6, NPDC1.
- chr9:137,077,517–137,084,539, 1 gene, copy number 6: UAP1L1.
- chr9:137,139,154–137,170,051, 3 genes, copy number 6: GRIN1, LRRC26, MIR3621.
- chr11:1,947,278–2,001,470, 7 genes, copy number 8–17: MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr16:680,224–692,554, 4 genes, copy number 9 (within-gene range 4–9): STUB1, JMJD8, WDR24, Z92544.1.
- chr16:784,974–800,737, 3 genes, copy number 5 (within-gene range 2–5): RPUSD1, CHTF18, GNG13.
- chr16:2,616,121–2,643,296, 1 gene, copy number 12 (within-gene range 1–12): PDPK2P.
- chr16:2,644,084–2,682,379, 2 genes, copy number 5–12: AC141586.2, ERVK13-1.
- chr16:88,651,935–88,663,161, 1 gene, copy number 8: MVD.
- chr16:88,696,499–88,715,396, 4 genes, copy number 5 (within-gene range 3–5): RNF166, AC138028.3, CTU2, AC138028.6.
- chr19:1,103,926–1,106,791, 1 gene, copy number 25: GPX4.
- chr19:1,238,179–1,239,522, 1 gene, copy number 55: AC004221.1.
- chr19:1,259,384–1,279,244, 3 genes, copy number 6–8: CIRBP, CIRBP-AS1, FAM174C.
- chr19:2,249,309–2,252,073, 2 genes, copy number 8: AMH, MIR4321.
- chr20:62,596,732–62,603,355, 1 gene, copy number 5: BX640514.2.
- chr20:62,640,719–62,643,304, 1 gene, copy number 5 (within-gene range 3–5): AL357033.1.
- chr20:63,488,013–63,499,239, 1 gene, copy number 12: EEF1A2.
- chr20:63,540,810–63,547,504, 2 genes, copy number 7: SRMS, AL121829.2.
- chr20:63,558,086–63,574,239, 1 gene, copy number 5: HELZ2.
- chr22:16,503,304–16,509,475, 1 gene, copy number 9: CHEK2P4.

Autosomal genes at a single copy (total copy number 1): 2,630. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
